Somatic mutation profile of tumor specimen C3N-03086-02 (aliquot CPT0209310007) from CPTAC case C3N-03086, project CPTAC-3 (Pancreas — Ductal and Lobular Neoplasms). Sex at birth: male; Vital status: Dead; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Pancreas, NOS; AJCC pathologic stage: Stage IIB; Tumor grade: G2; Age at diagnosis: 69.8 years (25,502 days).
Specimen C3N-03086-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Pancreas; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0d23c2a9-d74d-4840-886b-622f22a32112.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-03086-31 (Blood Derived Normal), aliquot CPT0209360002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/48249141-4c5d-467f-965e-8d79b9628f4c

The open-access MAF lists 47 somatic variants for this specimen: 37 protein-altering or splice-affecting, 4 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 31, Nonsense Mutation 4, Silent 4, Intron 3, 5'Flank 1, Splice Site 1, Frame Shift Del 1, RNA 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 54/272 reads (20%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- METTL14 | c.893G>A p.R298H | Missense Mutation (SNP) | VAF 24/157 reads (15%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66310162, COSV66310354; called by muse, mutect2, varscan2
- ADCYAP1R1 | c.857C>T p.T286M | Missense Mutation (SNP) | VAF 27/290 reads (9%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as rs200730426, COSV58443069; called by muse, mutect2
- ADD2 | c.14C>T p.T5M | Missense Mutation (SNP) | VAF 19/139 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.179); catalogued as rs782403508, COSV52459544; called by muse, mutect2, varscan2
- ARHGEF17 | c.5144G>A p.R1715H | Missense Mutation (SNP) | VAF 56/338 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1038055507; called by muse, mutect2, varscan2
- BCL6 | c.143C>T p.T48M | Missense Mutation (SNP) | VAF 29/215 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs200263685; ClinVar: not provided; called by muse, mutect2, varscan2
- CEP295 | c.5647C>T p.R1883* | Nonsense Mutation (SNP) | VAF 15/117 reads (13%) | catalogued as rs1468992629; called by muse, mutect2
- COL6A1 | c.2170G>A p.A724T | Missense Mutation (SNP) | VAF 44/347 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.59); catalogued as rs986553501, CM1211774, COSV62612515; called by muse, mutect2, varscan2
- CPNE9 | c.545+1G>A p.X182_splice | Splice Site (SNP) | VAF 31/104 reads (30%) | catalogued as rs1336728292; called by muse, mutect2, varscan2
- CSMD1 | c.8281G>A p.V2761M (on ENST00000520002; = p.V2760M on NM_033225.6) | Missense Mutation (SNP) | VAF 30/270 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs753927140, COSV59279948; called by muse, mutect2, varscan2
- ERG | c.484G>A p.V162I | Missense Mutation (SNP) | VAF 48/606 reads (8%) | SIFT tolerated (0.59); PolyPhen benign (0.09); catalogued as rs552037654, COSV55726607; called by muse, mutect2
- FAM184A | c.2189C>T p.T730M | Missense Mutation (SNP) | VAF 44/357 reads (12%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.944); catalogued as rs773464428, COSV58851698; called by muse, mutect2, varscan2
- GIGYF2 | c.2384G>T p.R795L | Missense Mutation (SNP) | VAF 18/155 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.451); catalogued as rs200601366; called by muse, mutect2, varscan2
- ISLR | c.446G>A p.R149H | Missense Mutation (SNP) | VAF 35/254 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as rs149796219, COSV51434720; called by muse, varscan2
- M6PR | c.796G>A p.E266K | Missense Mutation (SNP) | VAF 42/327 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.26); catalogued as rs780614862; called by muse, mutect2, varscan2
- MUC5AC | c.14303G>C p.S4768T | Missense Mutation (SNP) | VAF 42/328 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.124); catalogued as rs199611002, COSV64368850; called by muse, varscan2
- NCAM1 | c.1814C>T p.T605M (on ENST00000316851 / NM_181351.5; = p.T595M on NM_000615.7) | Missense Mutation (SNP) | VAF 22/233 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs782353037, COSV57517108; called by muse, mutect2
- OR2B3 | c.700C>T p.R234W | Missense Mutation (SNP) | VAF 26/124 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.97); catalogued as rs747253516, COSV65850780, COSV65851115; called by muse, mutect2, varscan2
- PCNX3 | c.1313C>T p.S438L | Missense Mutation (SNP) | VAF 22/187 reads (12%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.953); catalogued as rs766222339; called by muse, mutect2, varscan2
- PIWIL3 | c.869G>A p.R290Q | Missense Mutation (SNP) | VAF 25/230 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.853); catalogued as rs748965457, COSV59994067, COSV59994372; called by muse, mutect2, varscan2
- PNKP | c.302C>T p.P101L | Missense Mutation (SNP) | VAF 82/611 reads (13%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.581); catalogued as rs587784367, COSV55586028; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SKOR1 | c.1285G>A p.G429S | Missense Mutation (SNP) | VAF 10/64 reads (16%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.086); catalogued as rs780509897; called by muse, mutect2, varscan2
- TCERG1L | c.776C>T p.P259L | Missense Mutation (SNP) | VAF 9/64 reads (14%) | SIFT tolerated (0.26); PolyPhen benign (0.003); catalogued as rs535255286; called by muse, mutect2, varscan2
- TTC24 | c.343C>T p.R115* | Nonsense Mutation (SNP) | VAF 186/620 reads (30%) | catalogued as rs765487668; called by muse, mutect2, varscan2
- UHRF1BP1 | c.205C>T p.R69W | Missense Mutation (SNP) | VAF 16/108 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs754882631, COSV99512113; called by muse, mutect2, varscan2
- UNC119 | c.437C>T p.T146M | Missense Mutation (SNP) | VAF 30/295 reads (10%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.948); catalogued as rs767590360, COSV56379540; called by muse, mutect2
- ZNF32 | c.445G>A p.A149T | Missense Mutation (SNP) | VAF 18/161 reads (11%) | SIFT tolerated (0.39); PolyPhen benign (0.018); catalogued as rs939183137; called by muse, mutect2, varscan2
- CCN2 | c.838C>T p.R280* | Nonsense Mutation (SNP) | VAF 47/406 reads (12%) | called by muse, mutect2, varscan2
- FRAS1 | c.2817C>G p.Y939* | Nonsense Mutation (SNP) | VAF 8/92 reads (9%) | called by muse, mutect2
- FRMPD4 | c.268G>T p.G90C | Missense Mutation (SNP) | VAF 15/105 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GCM1 | c.1111G>T p.D371Y | Missense Mutation (SNP) | VAF 34/316 reads (11%) | SIFT tolerated (0.37); PolyPhen possibly damaging (0.87); called by muse, mutect2, varscan2
- MAST1 | c.3566G>A p.R1189H | Missense Mutation (SNP) | VAF 35/334 reads (10%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- METTL14 | c.117del p.D39Efs*46 | Frame Shift Del (DEL) | VAF 18/184 reads (10%) | called by mutect2, pindel, varscan2
- PDE4A | c.202G>A p.A68T | Missense Mutation (SNP) | VAF 60/419 reads (14%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.265); called by muse, mutect2, varscan2
- PLCXD3 | c.518C>A p.A173E | Missense Mutation (SNP) | VAF 24/220 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.25); called by muse, mutect2, varscan2
- PMS1 | c.326C>T p.T109I | Missense Mutation (SNP) | VAF 21/236 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.17); called by muse, mutect2
- RNF135 | c.319A>T p.S107C | Missense Mutation (SNP) | VAF 77/644 reads (12%) | SIFT tolerated (0.08); PolyPhen benign (0); called by muse, mutect2, varscan2
- ACAP2 | c.1035C>T p.S345= | Silent (SNP) | VAF 24/238 reads (10%) | catalogued as rs754957296; called by muse, mutect2
- BICD1 | c.2694C>T p.P898= | Silent (SNP) | VAF 37/235 reads (16%) | called by muse, mutect2, varscan2
- CBFA2T2 | c.546G>A p.L182= | Silent (SNP) | VAF 30/205 reads (15%) | called by muse, mutect2
- PLEKHG4B | c.993C>T p.L331= (on ENST00000283426; = p.L687= on NM_052909.5) | Silent (SNP) | VAF 32/341 reads (9%) | catalogued as rs141380436; called by muse, mutect2
- C9orf129 | n.627C>T | RNA (SNP) | VAF 54/532 reads (10%) | catalogued as rs773035660; called by muse, mutect2, varscan2
- CELF3 | c.773-16G>A | Intron (SNP) | VAF 47/170 reads (28%) | catalogued as rs560002386; called by muse, mutect2, varscan2
- DBF4B | c.1189+961G>A | Intron (SNP) | VAF 24/234 reads (10%) | catalogued as rs566628181; called by muse, mutect2, varscan2
- DDX1 | chr2:15591836 C>A | 5'Flank (SNP) | VAF 12/66 reads (18%) | called by muse, varscan2
- DIABLO | c.-37+1411G>A | Intron (SNP) | VAF 71/530 reads (13%) | catalogued as rs1388481840; called by muse, mutect2, varscan2
- RAI1 | c.*895G>A | 3'UTR (SNP) | VAF 12/87 reads (14%) | called by muse, mutect2
